Somatic mutation profile of tumor specimen TCGA-BP-4989-01A (aliquot TCGA-BP-4989-01A-01D-1462-08) from TCGA case TCGA-BP-4989, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 58.5 years (21,382 days).
Specimen TCGA-BP-4989-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d7704aa-0f91-4f4b-895c-8ea83259cacd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4989-11A (Solid Tissue Normal), aliquot TCGA-BP-4989-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c1f31f0-cd9d-42d1-bad2-a637357bb13f

The open-access MAF lists 72 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 44, Silent 19, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG8 | c.1521G>T p.W507C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55201428; called by muse, mutect2, varscan2
- AXIN1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV51990009; called by muse, mutect2, varscan2
- BACH1 | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV54518145; called by muse, mutect2, varscan2
- BRWD1 | c.3589T>C p.Y1197H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60899712; called by muse, mutect2, varscan2
- CCDC116 | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); catalogued as COSV99489305; called by muse, mutect2, varscan2
- CHD4 | c.4919A>C p.D1640A (on ENST00000357008 / NM_001363606.2; = p.D1651A on NM_001273.5) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.133); catalogued as COSV58906053; called by muse, mutect2, varscan2
- DGKG | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs775166597, COSV53968699; called by muse, mutect2, varscan2
- DHX34 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs767150327, COSV60896639; called by muse, mutect2, varscan2
- DHX36 | c.2699A>G p.Y900C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57673787, COSV57674941; called by muse, mutect2, varscan2
- EDIL3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs757863733, COSV56879041; called by muse, mutect2, varscan2
- EMC9 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV52824964; called by muse, mutect2, varscan2
- FAM135A | c.476T>G p.F159C (on ENST00000370479 / NM_001351599.1; = p.F116C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52055578; called by muse, mutect2, varscan2
- FAM193A | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV61196502; called by muse, mutect2, varscan2
- FLT4 | c.829A>C p.K277Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV56115825; called by muse, mutect2, varscan2
- FN1 | c.3469A>G p.R1157G | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.464); catalogued as COSV60558476; called by muse, mutect2, varscan2
- FOXI1 | c.745C>G p.Q249E | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV60389285; called by muse, mutect2
- FRMD7 | c.1612A>C p.I538L | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV53747643; called by muse, mutect2, varscan2
- GABRR1 | c.1249G>C p.G417R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.752); catalogued as COSV65619997; called by muse, mutect2, varscan2
- GPR78 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780580777, COSV66762610, COSV66764007; called by muse, mutect2, varscan2
- KIF13A | c.159G>A p.K53= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as COSV52458442; called by muse, mutect2, varscan2
- KIF2B | c.342A>C p.K114N | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV52133177; called by muse, mutect2, varscan2
- KMT2E | c.1248+1G>A p.X416_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | catalogued as COSV57576739; called by muse, mutect2, varscan2
- KRT1 | c.1894G>A p.V632M | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.44); catalogued as rs532003323, COSV52868090; called by muse, mutect2
- KRT85 | c.1074C>A p.C358* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as COSV57737564, COSV57738019; called by muse, mutect2, varscan2
- KRTAP13-2 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as rs771266402, COSV67762164; called by muse, mutect2, varscan2
- LATS1 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV53595400; called by muse, mutect2, varscan2
- LONRF3 | c.1493A>G p.N498S (on ENST00000371628 / NM_001031855.3; = p.N457S on NM_024778.5) | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs776334276, COSV59154818; called by muse, mutect2, varscan2
- LRRC3B | c.521C>A p.T174K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV101185755, COSV67521909; called by muse, mutect2, varscan2
- MAN2C1 | c.2455G>C p.V819L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs150703780, COSV51228189; called by muse, mutect2, varscan2
- MORC4 | c.1686-2A>T p.X562_splice | Splice Site (SNP) | VAF 9/51 reads (18%) | catalogued as COSV55244749; called by muse, mutect2, varscan2
- MYO3B | c.1507A>G p.T503A | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV58709951; called by muse, mutect2, varscan2
- OR51D1 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as COSV62914460; called by muse, mutect2
- OR8S1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | PolyPhen benign (0.003); catalogued as rs545295453, COSV59600325; called by muse, mutect2, varscan2
- PAAF1 | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.775); catalogued as COSV60156413; called by muse, mutect2, varscan2
- PCDH10 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52099190; called by muse, mutect2, varscan2
- PCDH9 | c.3163C>T p.L1055F (on ENST00000377865 / NM_203487.3; = p.L1021F on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV60570092; called by muse, mutect2, varscan2
- PCDHA7 | c.2250C>A p.F750L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs782091749, COSV65335356, COSV65336809; called by muse, mutect2, varscan2
- PLAU | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 26/97 reads (27%) | catalogued as rs375029894; called by muse, mutect2, varscan2
- PLXNB1 | c.2660T>C p.L887P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV56492077; called by muse, mutect2, varscan2
- PRKACG | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767187157, COSV55252928; called by muse, mutect2, varscan2
- RGS3 | c.1947C>G p.H649Q (on ENST00000350696 / NM_001282923.2; = p.H537Q on NM_017790.4) | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV58283029; called by muse, mutect2, varscan2
- ROBO1 | c.2474A>G p.H825R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV71396845; called by muse, mutect2
- ROBO1 | c.2472C>A p.Y824* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV71396846; called by muse, mutect2
- SEC14L5 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs776191007, COSV52040014, COSV52040462; called by muse, mutect2, varscan2
- SEC24B | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs751535639, COSV54503102; called by muse, mutect2, varscan2
- SLC7A1 | c.1498A>G p.T500A | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66331109; called by muse, mutect2
- SLIT3 | c.3194G>A p.G1065D | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60622176; called by muse, mutect2, varscan2
- VHL | c.346del p.L116Ffs*43 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as CM023998, CM951285, COSV56544954, COSV56545969; called by mutect2, pindel, varscan2
- WDR5B | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV58072813; called by muse, mutect2, varscan2
- XIRP2 | c.3490A>T p.K1164* (on ENST00000628543; = p.K1339* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | catalogued as COSV54717448; called by muse, mutect2, varscan2
- ZFP28 | c.1567C>A p.H523N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56736985; called by muse, mutect2, varscan2
- ZNF438 | c.806T>C p.M269T | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1238717498, COSV59198061; called by muse, mutect2, varscan2
- PBRM1 | c.3608_3609del p.E1203Afs*2 (on ENST00000296302 / NM_001366071.2; = p.E1178Afs*2 on NM_018313.5) | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- AXIN1 | c.735G>A p.E245= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV51990023; called by muse, mutect2
- COL6A2 | c.1530C>T p.P510= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs199842179, COSV56002059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERBB3 | c.1506A>G p.P502= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs1169761465, COSV57258493; called by muse, mutect2, varscan2
- FBXL4 | c.852T>G p.P284= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV57748265; called by muse, varscan2
- FLRT3 | c.819C>G p.L273= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV54016522; called by muse, mutect2, varscan2
- HOXB1 | c.57C>A p.P19= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as COSV53318030; called by muse, mutect2, varscan2
- IL16 | c.1908G>A p.A636= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs374086303; called by muse, mutect2, varscan2
- ILF3 | c.2466C>T p.G822= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV51560184; called by muse, mutect2, varscan2
- KIAA1217 | c.5559C>A p.L1853= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV100287212, COSV56819874; called by muse, mutect2, varscan2
- KLC1 | c.759C>T p.D253= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs200653403, COSV55809602; called by muse, mutect2, varscan2
- MED23 | c.987C>A p.L329= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV63434656, COSV63435817; called by muse, mutect2
- MFAP3 | c.489C>T p.L163= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as rs749082055, COSV59456848; called by muse, mutect2, varscan2
- PCDHA3 | c.1983C>A p.A661= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as COSV63543924; called by muse, mutect2, varscan2
- PCSK5 | c.3795G>A p.K1265= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV101377369; called by muse, varscan2
- PLEKHA5 | c.462T>C p.N154= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV54706558; called by muse, mutect2, varscan2
- TENM3 | c.6294C>G p.L2098= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs369904663, COSV69313956; called by muse, mutect2, varscan2
- TTN | c.41682A>G p.R13894= (on ENST00000591111; = p.R6470= on NM_003319.4) | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as COSV60195798; called by muse, mutect2, varscan2
- TTN | c.35829C>T p.L11943= (on ENST00000591111; = p.L4519= on NM_003319.4) | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV60195837; called by muse, mutect2, varscan2
- TTYH2 | c.1482C>T p.Y494= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs771307556, COSV53911945; called by muse, mutect2, varscan2
